Somatic mutation profile of tumor specimen 0DWGJJ from CCDI case PBCNSL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Odontogenic carcinosarcoma; Tissue or organ of origin: Maxillary sinus; Age at diagnosis: 9.8 years (3,597 days).
Specimen 0DWGJJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6690910-8b1d-44d2-8649-d5ade575011a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWGJ5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f88a369e-2d4a-49ff-8c12-eb671b8335a5

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 2, 3'UTR 2, In Frame Del 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJA9 | c.1199_1201del p.N400del | In Frame Del (DEL) | VAF 136/610 reads (22%) | catalogued as rs778669713; called by pindel, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 35/1071 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 40/853 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- LUC7L2 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- RTP2 | c.240C>T p.R80= | Silent (SNP) | VAF 102/716 reads (14%) | catalogued as rs1428483091, COSV64078743, COSV64079249; called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 28/821 reads (3%) | called by muse, mutect2
- DHX37 | c.2696-70T>C | Intron (SNP) | VAF 38/109 reads (35%) | catalogued as rs1467221068; called by muse, mutect2, varscan2
- PARG | c.-80C>T | 5'UTR (SNP) | VAF 20/59 reads (34%) | catalogued as rs1564674633; called by muse, mutect2, varscan2
- PDIA3 | c.-62C>G | 5'UTR (SNP) | VAF 47/152 reads (31%) | catalogued as rs1029195359, COSV100295273; called by muse, mutect2, varscan2
- TFF1 | c.*88G>A | 3'UTR (SNP) | VAF 79/229 reads (34%) | catalogued as rs571497302; called by muse, mutect2, varscan2
